Gene-level copy-number profile of tumor specimen TCGA-44-2659-01A from TCGA case TCGA-44-2659, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.2 years (23,808 days).
Specimen TCGA-44-2659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3fd0c70d-aea3-4b31-b63c-15b6e2ed3725.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-2659-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c0ad2d9-581c-4bce-ab19-54e8d4ae78be

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,150; copy number 2: 5,804; copy number 3: 26,072; copy number 4: 18,737; copy number 5: 1,656; copy number 6: 1,972; copy number 7: 69; copy number 8: 148; copy number 9: 51; copy number 10: 104; copy number 11: 965; copy number 15: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-2659-01A-01D-0944-01): tumor purity 0.42, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,427 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–65,023,310, 1,196 genes, copy number 8–15 (broad region; genes not listed).
- chr7:65,038,372–65,038,565, 1 gene, copy number 8: AC073210.2.
- chr7:147,831,770–148,801,110, 15 genes, copy number 7: RNU6-1184P, RNA5SP249, RN7SL456P, U3, RN7SL72P, AC083849.1, AC006974.1, AC006974.2, AC005229.2, AC005229.5, C7orf33, AC005229.1, AC005229.3, AC005229.4, CUL1.
- chr7:148,821,012–148,821,073, 1 gene, copy number 7: RNU7-20P.
- chr7:151,148,589–152,019,929, 27 genes, copy number 11 (within-gene range 4–11): GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5.
- chr11:100,641,975–100,687,955, 3 genes, copy number 9: RN7SL222P, PPIAP43, ARHGAP42-AS1.
- chr11:101,890,674–103,479,863, 48 genes, copy number 9 (within-gene range 5–9): ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr14:32,879,246–42,268,586, 136 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
